Somatic mutation profile of tumor specimen BA2746D (aliquot aq-BA2746D) from BEATAML1.0 case 2522, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.0 years (20,454 days).
Specimen BA2746D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 070cac0c-a4a2-4ac5-9095-edb86d22d4ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2693D (Solid Tissue Normal), aliquot aq-BA2693D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1395555-0d0b-4648-8d5f-6cb3da77a8b1

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- PLPPR3 | c.1283G>T p.S428I (on ENST00000520876 / NM_001270366.2; = p.S456I on NM_024888.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- RNF128 | c.1115C>A p.T372K (on ENST00000255499 / NM_194463.2; = p.T346K on NM_024539.3) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2
- LTB4R | c.375C>A p.S125= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
